Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7918, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7918-01A (Primary Tumor).

[page 1 of 4]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

LAB:

Phone

Final Report

DIAGNOSIS

A) LEFT HEPATIC LIGAMENT, BIOPSY:

1. Benign simple cyst
2. Background hepatic parenchyma is benign
3. Negative for malignancy

B) LYMPH NODE, HEPATIC ARTERY, BIOPSY:

1. One (1) benign lymph node is identified
2. Negative for malignancy

C) GALLBLADDER, CHOLECYSTECTOMY:

1. Unremarkable gallbladder
2. Negative for malignancy
3. A single (1) cystic duct lymph node is identified and is negative or malignancy

D) PANCREAS, PROXIMAL PARTIAL PANCREATECTOMY WITH TOTAL DUODENECTOMY AND ANASTOMOSIS (STANDARD WHIPPLE RESECTION):

1. Poorly differentiated adenocarcinoma, characterized by:
- a. Tumor size: 5.5 x 5 x 3.2 cm
- b. Tumor location: Pancreatic head
- c. Tumor extent: Extensive infiltration of the pancreatic parenchyma with extension into the peripancreatic adipose tissue
2. Extensive angiolymphatic space invasion and perineural invasion identified
3. Adenocarcinoma extends to involve the portal vein groove and portal vein margin (small fragment identified); remaining margins are negative- though the tumor comes to within 0.1 cm on the uncinate margin
4. Metastatic adenocarcinoma is identified in multiple (11 of 21) peripancreatic lymph nodes
- a. Extracapsular extension is identified
- b. The largest metastatic focus is 1.5 cm in greatest dimension
5. See staging summary

E) PORTAL VEIN, SEGMENTAL RE-EXCISION:

1. Portion of portal vein identified
2. Negative for malignancy

** PANCREATIC CANCER STAGING PARAMETERS **

Patient name:

Final TNM: pT3N1M0

stage: IIB

MACROSCOPIC

[page 2 of 4]
SPECIMEN TYPE

Whipple, Standard

TUMOR SITE

Pancreatic head

TUMOR SIZE

5.5 X 5 X 3.2 cm

MICROSCOPIC

HISTOLOGIC TYPE

Ductal Adenocarcinoma

HISTOLOGIC GRADE

G3: (poorly differentiated) of G4

MARGINS - PANCREATICO DUODECTOMY

Negative for invasive carcinoma, following re-excision of portal vein segment (specimen E)

Location(s): Portal vein groove and portal vein (from main specimen, part D)

Margin(s) evaluated: Bile duct, Distal pancreatic, Pancreatic retroperitoneal (uncinate)

LYMPHATIC/VASCULAR INVASION

Present: Lymph-vascular invasion present/identified

PERINEURAL INVASION

Present

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery)

REGIONAL LYMPH NODES

pN1. (Regional lymph node metastasis)

Total nodes: 21

Total positive nodes: 11

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE SUMMARY

Final TNM: pT3N1M0

stage: IIB

** The pathologic stage presumes no distant metastasis.

Attending Pathologist:

CLINICAL INFORMATION

A year-old male patient with pancreatic adenocarcinoma.

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Left hepatic ligament

Received fresh labeled "left hepatic ligament" is a 0.8 x 0.6 x 0.4 cm clear fluid-filled, smooth-walled translucent cyst. The cyst is bisected and entirely submitted on one chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Benign cyst" is rendered by

B) SOURCE: Hepatic artery lymph node

The specimen is received fresh labeled "hepatic artery lymph node." It consists of a 2.3 x 2 x 1.1 cm tan-red lymph node. It is serially sectioned and has a tan-red cut surface. It is entirely submitted for frozen on three

[page 3 of 4]
blocks.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "One (1) benign lymph node (0/1)" is rendered by [REDACTED]

C) SOURCE: Gallbladder

Labeled "gallbladder" is a purple-tan smooth surfaced 11 x 4 x 4 cm gallbladder. The serosal surface is smooth and glistening. The cystic duct is identified with a 0.3 cm luminal diameter. A 0.5 cm cystic duct lymph node is also seen. The specimen is opened revealing approximately 20 ml of thin green-brown bile. There are no calculi grossly identified. The mucosa is orange-green and velvety. The average wall thickness is 0.2 cm. Multiple representative sections of gallbladder wall, en face cystic duct margin and cystic duct lymph node are submitted in a single cassette.

D) SOURCE: Whipple

Received fresh labeled "Whipple" is a Whipple specimen which includes a 12 x 7 x 2.5 cm portion of stomach, 28 cm in length and averaging 3 cm in diameter segment of duodenum and a 9 x 6 x 4.5 cm portion of pancreas. The specimen is received inked in the usual fashion. The common bile duct is identified, displaying it to be dilated to 1.5 cm. It is taken en face and submitted on chuck #1. The distal pancreatic margin is taken en face and submitted on chuck #2. At the portal vein bed is an area of orange ink indicated by the surgeon as being an area of portal vein. This area is taken perpendicular and submitted on chuck #3.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Common bile duct margin negative for carcinoma. Distal pancreas en face margin negative. Portal vein groove and veins show involvement by poorly differentiated adenocarcinoma" is rendered by [REDACTED]

The common bile duct has a pigtail stent in place and is probe patent. It is opened revealing it to be slightly granular and focally stenosed to 0.5 cm. The pancreatic duct cannot be probed. The specimen is sectioned revealing a firm white tumor mass encompassing the majority of the pancreas measuring 5.5 x 5 x 3.2 cm. It extends to the portal vein bed, 0.1 cm from the distal pancreatic margin, 0.5 cm from the uncinate margin, 0.5 cm from the retroperitoneal margin. The tumor mass pushes the mucosa of the duodenum but does not extend through it. It has obliterated the pancreatic duct. There is a small area of normal-appearing pancreatic parenchyma in the proximal portion of the specimen. The ampulla is granular but otherwise unremarkable.

The stomach and duodenum mucosa are unremarkable and display no lesions.

Note: Tissue is taken for possible ancillary studies.

Photographs are taken.

The pancreatic fat is searched revealing 13 tan-pink lymph nodes, some of which are found in the parenchyma. They range from 0.5-2.6 cm in greatest dimension. The gastric fat is searched revealing no lymph nodes.

Sections of the pancreas are submitted from distal to proximal.

Representative sections are submitted in 27 cassettes labeled:

- DFS1. Frozen section, common bile duct
- DFS2. Frozen section, distal pancreatic margin
- DFS3. Frozen section, portal vein bed with portal vein

[page 4 of 4]
4. Proximal gastric margin
5. Distal duodenal margin
6. Random normal gastric and duodenal mucosa, unremarkable
7,8. Uncinate with retroperitoneum and portal vein bed margin
9. Distal tumor with adjacent lymph node
10-14. Representative tumor with common bile duct from distal to proximal with adjacent normal pancreas
15. Deep tumor serosa and possible lymph node
16. Three pancreatic lymph nodes, one bisected, inked blue
17. One lymph node
18. Two lymph nodes
19. One lymph node
20. Two lymph nodes, each bisected, one inked blue
21-23. Remainder of pancreatic fat
24,25. Representative gastric fat
26. Largest pancreatic lymph node, greatest dimension of tumor, representative
27. One pancreatic lymph node bisected

E) SOURCE: Vein segment, portal

Labeled "portal vein stitch on area of importance" consists of a wrinkled unoriented segment of apparent vasculature that has been previously opened. There are sutures on the outer aspect. The outer aspect with suture of area of importance is inked orange. The specimen is sectioned transversely and entirely submitted in a single cassette.

This case is accessioned in

MICROSCOPIC

A-E) The microscopic appearance substantiates the diagnosis.

Dictation by: transcribed by

Interpreted at

COLLECTED: ACCESSIONED: SIGNED:

Lab and Collection

Result History

Lab Status

Order Complete [3]

Result Information

Result Date and Time

Status

Provider Status

Final result

Reviewed

Source: NCI Genomic Data Commons file 4dd994b3-d72c-4b5e-849c-5dad05376b78 (TCGA-HZ-7918.66CC897F-570A-4F7D-B134-71AD8066D40E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).